CCDI case PBCJFM — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/d5f00c9b-c5e9-49b3-ad63-7f1a8fa90f22

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Dysembryoplastic neuroepithelial tumor: ICD-O-3 morphology code: 9413/0; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 4.9 years (1,800 days).

Biospecimens (3 samples)
- Sample 0DT4HZ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DT4I8: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DT4J7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
